Gene-level copy-number profile of tumor specimen TCGA-D3-A8GB-06A from TCGA case TCGA-D3-A8GB, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 49.0 years (17,905 days).
Specimen TCGA-D3-A8GB-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.4d888ace-079b-48fd-be1f-a7b6cce86102.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D3-A8GB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d257409a-ac24-49c4-9361-0ddc4cfa1b91

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 17,006; copy number 2: 37,898; copy number 3: 4,122; copy number 4: 185; copy number 5: 39; copy number 6: 88; copy number 7: 113; copy number 8: 62; copy number 9: 102; copy number 10: 170; copy number 13: 35.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D3-A8GB-06A-11D-A371-01): tumor purity 0.33, ploidy 1.92, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 609 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:66,435,075–78,175,323, 427 genes, copy number 6–13 (within-gene range 4–13) (broad region; genes not listed).
- chr11:95,821,766–106,469,296, 125 genes, copy number 5–13 (broad region; genes not listed).
- chr19:19,264,364–20,321,305, 57 genes, copy number 10 (within-gene range 2–10): TM6SF2, SUGP1, MAU2, GATAD2A, AC092067.1, MIR640, TSSK6, NDUFA13, AC011448.1, YJEFN3, CILP2, PBX4, PHF5CP, AC002306.1, LPAR2, GMIP, ATP13A1, ZNF101, AC011458.2, AC011458.1, ZNF14, AC011477.6, AC011477.7, AC011477.5, LINC00663, AC011477.8, AC011477.3, AC011477.4, ZNF56, ZNF506, AC011477.1, BNIP3P9, ZNF253, BNIP3P10, AC011477.2, ZNF93, AC007204.1, AC007204.2, ZNF682, AC006539.2, AC006539.3, BNIP3P13, ZNF90, AC006539.1, AC011447.5, AC011447.3, AC011447.1, AC011447.2, BNIP3P15, ZNF486, BNIP3P16, AC011447.4, AC011447.6, AC011447.7, BNIP3P17, AC078899.3, AC078899.1.

Autosomal genes at a single copy (total copy number 1): 14,585. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
